Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4267, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4267-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Body, posterior wall. Tumor configuration: Not specified. Tumor size: 5 x 5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Muscularis propria. Lymph nodes: Negative for metastasis. Margins— Proximal margin: Uninvolved by invasive carcinoma. Distal margin: Uninvolved by invasive carcinoma. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 2b227a0c-f97b-4240-8bfa-5fc50253a918 (TCGA-BR-4267.20266C95-C38B-4289-B3DF-1BABEADC48BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).